Somatic mutation profile of tumor specimen TCGA-CW-6093-01A (aliquot TCGA-CW-6093-01A-11D-1669-08) from TCGA case TCGA-CW-6093, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 73.7 years (26,909 days).
Specimen TCGA-CW-6093-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86e57666-6ac7-4520-9bcc-9111d2c5098e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CW-6093-11A (Solid Tissue Normal), aliquot TCGA-CW-6093-11A-01D-1669-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/52f660d7-93d9-4470-a363-8fda7e669e8b

The open-access MAF lists 116 somatic variants for this specimen: 88 protein-altering or splice-affecting, 25 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 25, Frame Shift Del 11, Splice Site 4, Nonsense Mutation 3, Frame Shift Ins 2, 5'UTR 1, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTL9 | c.1150G>A p.G384S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs890195620, COSV61005681; called by muse, mutect2, varscan2
- AGRN | c.4805C>A p.P1602H | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.533); catalogued as COSV65069363; called by muse, mutect2, varscan2
- AMER3 | c.1318G>A p.D440N | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as COSV58466554; called by muse, mutect2, varscan2
- ANK3 | c.216G>C p.Q72H | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55056390; called by muse, mutect2, varscan2
- ANKRD11 | c.7319A>C p.E2440A | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56360283; called by muse, mutect2, varscan2
- ATXN2 | c.3687T>G p.H1229Q (on ENST00000550104; = p.H1069Q on NM_002973.4) | Missense Mutation (SNP) | VAF 52/237 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57983069; called by muse, mutect2, varscan2
- ATXN2 | c.3686A>T p.H1229L (on ENST00000550104; = p.H1069L on NM_002973.4) | Missense Mutation (SNP) | VAF 55/239 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57983077; called by muse, mutect2, varscan2
- BABAM2 | c.875A>C p.E292A | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.184); catalogued as COSV59622447; called by muse, mutect2, varscan2
- BRD2 | c.254T>C p.V85A | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.571); catalogued as COSV66373187; called by muse, mutect2, varscan2
- C12orf43 | c.517C>G p.Q173E | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as COSV56567124; called by muse, mutect2, varscan2
- C12orf56 | c.1325A>G p.N442S (on ENST00000543942 / NM_001170633.2; = p.N282S on NM_001099676.3) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.124); catalogued as COSV61486814; called by muse, mutect2, varscan2
- C14orf93 | c.1061A>T p.N354I | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.962); catalogued as COSV54440953; called by muse, mutect2, varscan2
- C16orf70 | c.355+2T>G p.X119_splice | Splice Site (SNP) | VAF 45/160 reads (28%) | catalogued as COSV54627123; called by muse, mutect2, varscan2
- CASQ1 | c.783-2A>G p.X261_splice | Splice Site (SNP) | VAF 30/102 reads (29%) | catalogued as COSV63624125; called by muse, mutect2, varscan2
- CD1D | c.515C>A p.T172K | Missense Mutation (SNP) | VAF 59/334 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs536931854, COSV63808941, COSV63809408; called by muse, mutect2, varscan2
- CELSR2 | c.4487G>A p.G1496E | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54771031; called by muse, mutect2, varscan2
- CFAP47 | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs371807838, COSV52884079; called by muse, mutect2, varscan2
- CHRM3 | c.977A>G p.Q326R | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as COSV55088160; called by muse, mutect2, varscan2
- CUL7 | c.2966A>G p.Y989C | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.836); catalogued as COSV54816361; called by muse, mutect2
- CYB561A3 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as COSV53651839; called by muse, mutect2, varscan2
- DENND1A | c.2353C>T p.L785F | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV65349896; called by muse, mutect2
- DENND2A | c.673A>G p.R225G | Missense Mutation (SNP) | VAF 62/277 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as COSV52050888; called by muse, mutect2, varscan2
- DHX15 | c.2023C>T p.R675C | Missense Mutation (SNP) | VAF 24/328 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV61026804; called by muse, mutect2
- DLGAP5 | c.113A>G p.E38G | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.48); catalogued as COSV55963112; called by muse, mutect2, varscan2
- ERBB4 | c.3161C>A p.P1054H | Missense Mutation (SNP) | VAF 46/181 reads (25%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.994); catalogued as COSV61484339; called by muse, mutect2, varscan2
- EVI5 | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.917); catalogued as COSV63278652; called by muse, mutect2, varscan2
- EXD3 | c.813C>A p.C271* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as COSV59807006; called by muse, mutect2, varscan2
- FAM166B | c.453G>T p.E151D | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV63428479; called by muse, mutect2, varscan2
- FAT3 | c.9288C>G p.I3096M | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.168); catalogued as COSV53105993; called by muse, mutect2, varscan2
- FMNL3 | c.841G>A p.G281R | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53301451; called by muse, varscan2
- FZR1 | c.48G>C p.Q16H | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.179); catalogued as rs1160145563, COSV58051719; called by muse, mutect2, varscan2
- GPALPP1 | c.420C>A p.S140R | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV62705743; called by muse, mutect2, varscan2
- H1-10 | c.564G>C p.K188N | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as COSV61549657; called by muse, mutect2, varscan2
- HECW2 | c.1459G>A p.G487S | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.257); catalogued as rs752934289, COSV53658198; called by muse, mutect2, varscan2
- HPS5 | c.1814C>A p.P605Q (on ENST00000349215 / NM_181507.2; = p.P491Q on NM_007216.4) | Missense Mutation (SNP) | VAF 52/183 reads (28%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.468); catalogued as COSV61687441; called by muse, mutect2, varscan2
- KIAA1217 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64605219; called by muse, mutect2, varscan2
- KIF14 | c.199T>A p.Y67N | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66261569; called by muse, mutect2, varscan2
- KIRREL1 | c.698C>G p.T233R | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV63286926, COSV63290072; called by muse, mutect2, varscan2
- LIMS2 | c.158G>C p.G53A (on ENST00000355119 / NM_001161403.3; = p.G77A on NM_017980.4) | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV55755021; called by muse, mutect2, varscan2
- LTBP1 | c.1475A>C p.E492A (on ENST00000404816 / NM_206943.4; = p.E166A on NM_000627.4) | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.81); catalogued as COSV63186025; called by muse, mutect2, varscan2
- MACF1 | c.19024C>G p.L6342V (on ENST00000372915; = p.L4387V on NM_012090.5) | Missense Mutation (SNP) | VAF 22/109 reads (20%) | catalogued as COSV57119618; called by muse, mutect2, varscan2
- MAGEC1 | c.1604G>C p.S535T | Missense Mutation (SNP) | VAF 102/192 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.307); catalogued as COSV53572255, COSV53575195; called by muse, mutect2, varscan2
- MANSC1 | c.631T>G p.S211A | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as COSV67110986; called by muse, mutect2, varscan2
- MAP3K4 | c.1623G>T p.K541N | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV62333139; called by muse, mutect2, varscan2
- MAPK13 | c.354G>T p.M118I | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV52983011; called by muse, mutect2, varscan2
- MAST3 | c.2627A>G p.K876R | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.007); catalogued as COSV53220303; called by muse, mutect2, varscan2
- METTL25 | c.1191A>G p.I397M | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.179); catalogued as rs374095144; called by muse, mutect2, varscan2
- NEURL4 | c.3325G>C p.E1109Q | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.167); catalogued as COSV100223200, COSV59749331; called by muse, mutect2, varscan2
- NFAT5 | c.734A>T p.K245I | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63027199; called by muse, mutect2, varscan2
- NUDT10 | c.107T>C p.V36A | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62854123; called by muse, mutect2, varscan2
- OR6C2 | c.278A>G p.N93S | Missense Mutation (SNP) | VAF 75/319 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.029); catalogued as COSV59515983; called by muse, mutect2, varscan2
- OR8G5 | c.793G>A p.V265I | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.102); catalogued as rs777070624, COSV58380918, COSV58381958; called by muse, mutect2, varscan2
- PBRM1 | c.715-1G>A p.X239_splice | Splice Site (SNP) | VAF 28/85 reads (33%) | catalogued as COSV56266801, COSV56273492; called by muse, mutect2, varscan2
- PLEKHA2 | c.1121C>A p.S374* | Nonsense Mutation (SNP) | VAF 5/10 reads (50%) | catalogued as COSV56759253; called by muse, mutect2, varscan2
- PLPP3 | c.50G>C p.G17A | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.919); catalogued as COSV64839326; called by muse, mutect2, varscan2
- PLS1 | c.1668A>T p.L556F | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61833729; called by muse, mutect2, varscan2
- PODXL | c.1234G>C p.E412Q (on ENST00000378555 / NM_001018111.3; = p.E380Q on NM_005397.4) | Missense Mutation (SNP) | VAF 51/224 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.211); catalogued as COSV100539046, COSV59870098; called by muse, mutect2, varscan2
- PPP4R3B | c.1030dup p.S344Ffs*26 | Frame Shift Ins (INS) | VAF 34/140 reads (24%) | catalogued as rs35266904; called by mutect2, pindel, varscan2
- RANBP2 | c.911G>A p.S304N | Missense Mutation (SNP) | VAF 110/401 reads (27%) | SIFT tolerated (0.23); catalogued as COSV51700490; called by muse, mutect2, varscan2
- RASSF3 | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as COSV51685126; called by muse, mutect2, varscan2
- REG3G | c.512G>T p.C171F | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55448609, COSV55449357; called by muse, mutect2, varscan2
- SNAI2 | c.329A>T p.E110V | Missense Mutation (SNP) | VAF 80/271 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.045); catalogued as COSV50078981; called by muse, mutect2, varscan2
- SORCS3 | c.3387G>A p.M1129I | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.318); catalogued as COSV63809289; called by muse, mutect2, varscan2
- THEG | c.124G>A p.V42I | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.006); catalogued as rs1357101769, COSV61073776; called by muse, mutect2, varscan2
- TRIM51 | c.940G>T p.D314Y | Missense Mutation (SNP) | VAF 42/200 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.481); catalogued as COSV55265486, COSV55266209; called by muse, mutect2, varscan2
- TTN | c.80542G>C p.E26848Q (on ENST00000591111; = p.E19424Q on NM_003319.4) | Missense Mutation (SNP) | VAF 10/51 reads (20%) | PolyPhen probably damaging (0.997); catalogued as COSV60031266, COSV60265292; called by muse, mutect2, varscan2
- TTN | c.79132T>A p.S26378T (on ENST00000591111; = p.S18954T on NM_003319.4) | Missense Mutation (SNP) | VAF 12/48 reads (25%) | PolyPhen benign (0); catalogued as rs1459825142, COSV60031302; called by muse, mutect2, varscan2
- WDR55 | c.998A>C p.D333A | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV56906653; called by muse, mutect2, varscan2
- XIRP2 | c.6458C>T p.S2153L (on ENST00000628543; = p.S2328L on NM_152381.6) | Missense Mutation (SNP) | VAF 70/251 reads (28%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs750820952, COSV54697784; called by muse, mutect2, varscan2
- XRN1 | c.4795C>T p.H1599Y | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV53811307, COSV53818912; called by muse, mutect2
- ZFP14 | c.772T>C p.C258R | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54202269; called by muse, mutect2, varscan2
- ZFYVE27 | c.557A>G p.Y186C | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs575306476, COSV61746627; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF202 | c.888G>A p.W296* | Nonsense Mutation (SNP) | VAF 23/81 reads (28%) | catalogued as COSV60247017; called by muse, mutect2, varscan2
- ZNF710 | c.1474A>C p.K492Q | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV51562896; called by muse, mutect2, varscan2
- ZYX | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 49/296 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.922); catalogued as rs777343615, COSV59556364; called by muse, mutect2, varscan2
- AJUBA | c.1416del p.S473Lfs*8 | Frame Shift Del (DEL) | VAF 13/71 reads (18%) | called by mutect2, pindel, varscan2
- AMBRA1 | c.3005_3006del p.P1002Rfs*17 (on ENST00000458649 / NM_001367468.1; = p.P912Rfs*17 on NM_017749.3 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 15/88 reads (17%) | called by mutect2, pindel, varscan2
- CCDC17 | c.1006del p.Q336Nfs*34 | Frame Shift Del (DEL) | VAF 7/25 reads (28%) | called by mutect2, pindel, varscan2
- FERMT3 | c.1770_1771del p.K590Nfs*24 (on ENST00000279227 / NM_178443.3; = p.K586Nfs*24 on NM_031471.6 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 22/100 reads (22%) | called by mutect2, pindel, varscan2
- GTSE1 | c.1944del p.K649Nfs*34 | Frame Shift Del (DEL) | VAF 50/221 reads (23%) | called by mutect2, pindel, varscan2
- MMP10 | c.187del p.I63Sfs*12 | Frame Shift Del (DEL) | VAF 10/57 reads (18%) | called by mutect2, pindel, varscan2
- MYH4 | c.2942del p.N981Tfs*16 | Frame Shift Del (DEL) | VAF 37/203 reads (18%) | called by mutect2, pindel, varscan2
- NAPRT | c.1271del p.F424Sfs*17 | Frame Shift Del (DEL) | VAF 25/121 reads (21%) | called by mutect2, pindel, varscan2
- NRDC | c.1421+1dup p.X474_splice | Splice Site (INS) | VAF 19/60 reads (32%) | called by mutect2, pindel, varscan2
- SENP7 | c.680del p.G227Afs*8 | Frame Shift Del (DEL) | VAF 32/130 reads (25%) | called by mutect2, pindel, varscan2
- SLC44A1 | c.1265del p.N422Ifs*11 | Frame Shift Del (DEL) | VAF 17/77 reads (22%) | called by mutect2, pindel, varscan2
- TAB2 | c.820_821insT p.N274Ifs*30 | Frame Shift Ins (INS) | VAF 28/139 reads (20%) | called by mutect2, pindel, varscan2
- VHL | c.369del p.T124Hfs*35 | Frame Shift Del (DEL) | VAF 48/175 reads (27%) | called by mutect2, pindel, varscan2
- AGBL1 | c.2674C>A p.R892= | Silent (SNP) | VAF 25/190 reads (13%) | catalogued as COSV66857185; called by muse, mutect2, varscan2
- AP3M1 | c.1015C>T p.L339= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as rs777878319, COSV53009075; called by muse, mutect2, varscan2
- APOBR | c.2397A>G p.E799= (on ENST00000431282; = p.E808= on NM_018690.4) | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV60490610; called by muse, mutect2, varscan2
- ARHGAP5 | c.4041A>G p.P1347= (on ENST00000345122 / NM_001030055.2; = p.P1346= on NM_001173.3) | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV53735152; called by muse, mutect2, varscan2
- CD200 | c.150G>C p.V50= (on ENST00000473539 / NM_001004196.3; = p.V25= on NM_005944.7 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV59863157; called by muse, mutect2, varscan2
- CDC25C | c.1225C>T p.L409= | Silent (SNP) | VAF 51/168 reads (30%) | catalogued as COSV60399264; called by muse, mutect2, varscan2
- CLCN2 | c.42G>C p.A14= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as COSV55600980, COSV55604962; called by muse, mutect2, varscan2
- CLCN5 | c.1320C>T p.V440= | Silent (SNP) | VAF 16/29 reads (55%) | catalogued as COSV56583731; called by muse, mutect2, varscan2
- GIMAP8 | c.1374C>T p.I458= | Silent (SNP) | VAF 58/147 reads (39%) | catalogued as COSV56231199; called by muse, mutect2, varscan2
- IL31 | c.462A>G p.S154= | Silent (SNP) | VAF 20/113 reads (18%) | catalogued as COSV65476299; called by muse, mutect2, varscan2
- LAMA1 | c.1818G>A p.S606= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs552854758, COSV67536351; called by mutect2, varscan2
- MRE11 | c.282C>A p.L94= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV60576569; called by muse, mutect2, varscan2
- MYO18B | c.858A>T p.G286= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV59133332; called by mutect2, varscan2
- NEDD4 | c.1005C>T p.P335= | Silent (SNP) | VAF 39/167 reads (23%) | catalogued as rs753137897, COSV59061408; called by muse, mutect2, varscan2
- NOM1 | c.1554T>G p.A518= | Silent (SNP) | VAF 33/166 reads (20%) | catalogued as COSV51979985; called by muse, mutect2, varscan2
- PIK3C2A | c.4135T>C p.L1379= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as rs750211569, COSV56402478; called by muse, mutect2, varscan2
- PLCG1 | c.2316G>T p.G772= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV54818197; called by muse, mutect2, varscan2
- POLR1E | c.1143C>T p.Y381= (on ENST00000377792 / NM_001282766.1; = p.Y319= on NM_022490.4) | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV66772032; called by muse, mutect2, varscan2
- PSMA3 | c.69A>G p.Q23= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as COSV53617038; called by muse, mutect2, varscan2
- SLC17A7 | c.1335C>T p.G445= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV55547593; called by muse, mutect2, varscan2
- SPTSSB | c.84C>A p.P28= | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as COSV63219172; called by muse, mutect2, varscan2
- TECTA | c.477C>T p.S159= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as COSV50704894; called by muse, mutect2, varscan2
- TP53BP2 | c.2286G>A p.R762= (on ENST00000343537 / NM_001031685.3; = p.R633= on NM_005426.2) | Silent (SNP) | VAF 43/179 reads (24%) | catalogued as COSV59068217; called by muse, mutect2, varscan2
- ZFHX3 | c.2568C>T p.P856= | Silent (SNP) | VAF 20/81 reads (25%) | catalogued as rs1181169491, COSV51717255; called by muse, mutect2, varscan2
- ZNF131 | c.444A>G p.A148= | Silent (SNP) | VAF 36/121 reads (30%) | catalogued as COSV61002370; called by muse, mutect2, varscan2
- PUM1 | c.-2G>A | 5'UTR (SNP) | VAF 36/109 reads (33%) | catalogued as COSV99929058; called by muse, mutect2, varscan2
- SND1 | c.2110+424A>G | Intron (SNP) | VAF 24/155 reads (15%) | catalogued as COSV61240249; called by muse, mutect2, varscan2
- SNX18 | chr5:54543409 C>A | 3'Flank (SNP) | VAF 26/88 reads (30%) | catalogued as COSV57989053; called by muse, mutect2, varscan2
